Somatic mutation profile of tumor specimen TCGA-HU-8610-01A (aliquot TCGA-HU-8610-01A-22D-2394-08) from TCGA case TCGA-HU-8610, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IA; Tumor grade: G2; Age at diagnosis: 75.5 years (27,594 days).
Specimen TCGA-HU-8610-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 43ece74e-29e5-4c76-959a-449d834904b6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HU-8610-10A (Blood Derived Normal), aliquot TCGA-HU-8610-10A-01D-2394-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4212c22c-36fd-49d7-879f-24222fad824e

The open-access MAF lists 62 somatic variants for this specimen: 49 protein-altering or splice-affecting, 13 silent.
By variant classification: Missense Mutation 44, Silent 13, Nonsense Mutation 4, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC10 | c.1969G>A p.V657M (on ENST00000372530 / NM_001198934.2; = p.V629M on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/107 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.394); catalogued as COSV55091502; called by muse, mutect2, varscan2
- ANK2 | c.4159G>A p.G1387S | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751096182, COSV52175895; called by muse, mutect2, varscan2
- APBA3 | c.1387G>A p.A463T | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.837); catalogued as rs575676926, COSV53661364; called by muse, mutect2
- CACNA1B | c.373C>T p.P125S | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs200696346, COSV53138227; called by muse, mutect2, varscan2
- CECR2 | c.772G>A p.E258K (on ENST00000342247 / NM_001290047.2; = p.E95K on NM_001290046.1) | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.923); catalogued as rs377480686; called by muse, mutect2, varscan2
- CER1 | c.749G>A p.G250E | Missense Mutation (SNP) | VAF 22/113 reads (19%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV66603699; called by muse, mutect2, varscan2
- COBLL1 | c.700C>T p.Q234* (on ENST00000392717; = p.Q196* on NM_014900.5) | Nonsense Mutation (SNP) | VAF 13/76 reads (17%) | catalogued as COSV52072300; called by muse, mutect2, varscan2
- COL4A3 | c.1103G>A p.R368H | Missense Mutation (SNP) | VAF 18/137 reads (13%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as rs748026747, COSV67417698; called by muse, mutect2, varscan2
- DOCK2 | c.3190C>T p.R1064W | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as rs772417044, COSV56956155; called by muse, mutect2, varscan2
- DYTN | c.1231G>T p.G411* | Nonsense Mutation (SNP) | VAF 10/76 reads (13%) | catalogued as COSV71751831, COSV71752604; called by muse, mutect2, varscan2
- EIF2AK2 | c.672T>G p.S224R | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as COSV51798045; called by muse, mutect2, varscan2
- FBXL12 | c.520C>T p.R174C | Missense Mutation (SNP) | VAF 21/116 reads (18%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.635); catalogued as rs562812843, COSV56114664; called by muse, mutect2, varscan2
- FLG | c.4639G>A p.E1547K | Missense Mutation (SNP) | VAF 66/551 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs1220069584, COSV64245113; called by muse, mutect2, varscan2
- GRIA1 | c.1195G>A p.G399S | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV53598454, COSV53614671; called by muse, mutect2, varscan2
- IL12RB2 | c.707A>C p.K236T | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as rs201771864, COSV99254764; called by muse, mutect2, varscan2
- KCNA3 | c.407G>A p.R136H | Missense Mutation (SNP) | VAF 25/179 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63902221; called by muse, mutect2, varscan2
- KRT31 | c.266G>A p.R89Q | Missense Mutation (SNP) | VAF 31/128 reads (24%) | SIFT tolerated (0.56); PolyPhen benign (0.014); catalogued as rs775196792, COSV52434308; called by muse, mutect2, varscan2
- LRFN3 | c.842G>A p.R281H | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs748422900, COSV55818484; called by muse, mutect2, varscan2
- LRRN3 | c.1213C>T p.Q405* | Nonsense Mutation (SNP) | VAF 12/78 reads (15%) | catalogued as COSV57822134; called by muse, mutect2, varscan2
- MAP2K7 | c.1087A>G p.K363E | Missense Mutation (SNP) | VAF 39/120 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV67609138; called by muse, mutect2, varscan2
- NAV3 | c.2232G>T p.L744F | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV57097821; called by muse, mutect2
- NELFCD | c.282A>C p.E94D (on ENST00000602795; = p.E76D on NM_198976.4) | Missense Mutation (SNP) | VAF 33/268 reads (12%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as COSV59747874; called by muse, mutect2, varscan2
- NSUN6 | c.1268G>A p.R423Q | Missense Mutation (SNP) | VAF 29/294 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763020178, COSV56618570, COSV99995279; called by muse, mutect2, varscan2
- NYAP2 | c.1486G>A p.G496R | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.396); catalogued as rs907521109, COSV56011683; called by muse, mutect2, varscan2
- OBSCN | c.32G>A p.R11H | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV52802358; called by muse, mutect2, varscan2
- PCDHGB4 | c.1867G>A p.E623K | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV53919987; called by muse, mutect2, varscan2
- PIK3C2B | c.1249A>G p.R417G | Missense Mutation (SNP) | VAF 19/217 reads (9%) | SIFT tolerated (0.45); PolyPhen benign (0.113); catalogued as COSV65803922; called by muse, mutect2
- PRAMEF12 | c.829T>A p.S277T | Missense Mutation (SNP) | VAF 18/228 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.23); catalogued as COSV63216046; called by muse, mutect2
- PXDNL | c.2161C>T p.R721W | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.093); catalogued as rs1263551229, COSV62493717; called by muse, mutect2, varscan2
- RGS20 | c.1149G>T p.E383D (on ENST00000297313 / NM_170587.4; = p.E236D on NM_003702.4) | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.601); catalogued as COSV52020070; called by muse, mutect2, varscan2
- RNF165 | c.145G>A p.A49T | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as COSV53972037; called by muse, mutect2, varscan2
- SIGLEC10 | c.542C>T p.T181M | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.063); catalogued as rs765754593, COSV59479721; called by muse, mutect2, varscan2
- SLC24A5 | c.800G>A p.G267E | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs774546543, COSV51050325; called by muse, mutect2, varscan2
- SLITRK2 | c.1045C>T p.Q349* | Nonsense Mutation (SNP) | VAF 10/40 reads (25%) | catalogued as COSV59427026, COSV59427405; called by muse, mutect2, varscan2
- SOS2 | c.462T>A p.H154Q | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.957); catalogued as COSV53571089; called by mutect2, varscan2
- STK4 | c.719C>G p.P240R | Missense Mutation (SNP) | VAF 13/144 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV65671289; called by muse, mutect2
- STYXL1 | c.392A>G p.Y131C | Missense Mutation (SNP) | VAF 67/355 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs782347485, COSV50390720; called by muse, mutect2, varscan2
- TG | c.4192C>T p.R1398C | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.791); catalogued as rs140482581, COSV55086797; called by muse, mutect2, varscan2
- TP53BP1 | c.2300G>A p.R767K | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT tolerated, low confidence (0.48); PolyPhen probably damaging (0.952); catalogued as COSV55500559, COSV55505352; called by muse, mutect2, varscan2
- TRIM32 | c.1654A>T p.I552F | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.884); catalogued as COSV57799555; called by muse, mutect2
- TSHZ3 | c.778C>T p.R260C | Missense Mutation (SNP) | VAF 42/336 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as rs200052169, COSV53677379; called by muse, mutect2, varscan2
- TTN | c.987G>C p.K329N | Missense Mutation (SNP) | VAF 24/98 reads (24%) | PolyPhen possibly damaging (0.526); catalogued as COSV60208651, COSV60343806; called by muse, mutect2, varscan2
- YIPF1 | c.62C>A p.A21E | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT tolerated (0.74); PolyPhen benign (0.205); catalogued as COSV50778430; called by muse, mutect2
- ZNF418 | c.767G>T p.R256I | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.879); catalogued as rs773421915, COSV68675884, COSV68676161; called by muse, varscan2
- ZNF488 | c.617G>A p.R206Q | Missense Mutation (SNP) | VAF 18/166 reads (11%) | SIFT tolerated (0.69); PolyPhen benign (0.006); catalogued as rs781991498; called by muse, mutect2
- ZNF835 | c.791C>T p.A264V | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.712); catalogued as COSV73379611; called by muse, mutect2
- PIGW | c.908G>T p.R303L | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TBC1D3F | c.772G>A p.D258N | Missense Mutation (SNP) | VAF 18/352 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.397); called by muse, mutect2
- TP53 | c.757_777del p.T253_D259del | In Frame Del (DEL) | VAF 6/64 reads (9%) | called by mutect2, pindel
- ANKRD12 | c.288T>G p.S96= | Silent (SNP) | VAF 7/58 reads (12%) | catalogued as COSV50836408; called by muse, mutect2, varscan2
- BLK | c.42G>A p.P14= | Silent (SNP) | VAF 13/89 reads (15%) | catalogued as rs775316612, COSV52050447; called by muse, mutect2, varscan2
- CCBE1 | c.810C>T p.P270= | Silent (SNP) | VAF 19/106 reads (18%) | catalogued as rs151243930; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ERC2 | c.1140C>T p.I380= | Silent (SNP) | VAF 12/62 reads (19%) | catalogued as rs1350866004, COSV55635602; called by muse, mutect2
- FBXO44 | c.120C>A p.L40= | Silent (SNP) | VAF 16/117 reads (14%) | catalogued as COSV52354907; called by muse, mutect2, varscan2
- LAMA1 | c.3579G>C p.G1193= | Silent (SNP) | VAF 9/18 reads (50%) | catalogued as COSV67540628; called by muse, mutect2, varscan2
- LRRK2 | c.141C>T p.Y47= | Silent (SNP) | VAF 3/43 reads (7%) | called by muse, mutect2
- LTBP1 | c.681G>A p.S227= | Silent (SNP) | VAF 37/347 reads (11%) | catalogued as rs770467593, COSV63193492; called by muse, mutect2, varscan2
- NTSR1 | c.1242C>A p.R414= | Silent (SNP) | VAF 16/108 reads (15%) | catalogued as rs73918683, COSV65138658; called by muse, varscan2
- PCDHA7 | c.1245C>T p.R415= | Silent (SNP) | VAF 44/271 reads (16%) | catalogued as rs1554135129, COSV65346043; called by muse, mutect2, varscan2
- PTGDR | c.357G>A p.S119= | Silent (SNP) | VAF 24/269 reads (9%) | catalogued as rs1053173203, COSV60094596; called by muse, mutect2
- SPEG | c.7983C>T p.N2661= | Silent (SNP) | VAF 19/95 reads (20%) | catalogued as rs200645290, COSV56675394; called by muse, mutect2, varscan2
- ZNF511 | c.255C>G p.A85= | Silent (SNP) | VAF 14/131 reads (11%) | catalogued as COSV62920371; called by muse, mutect2, varscan2
